Somatic mutation profile of tumor specimen TARGET-10-PARPYS-09A (aliquot TARGET-10-PARPYS-09A-01D) from TARGET case TARGET-10-PARPYS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.7 years (5,372 days).
Specimen TARGET-10-PARPYS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2679892-8099-4c12-93b0-0d09a55e7f0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPYS-14A (Bone Marrow Normal), aliquot TARGET-10-PARPYS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a996bfe0-b9ca-4980-b1fd-8a4edc933ca8

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, In Frame Ins 1, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMIGO3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57537835; called by muse, mutect2, varscan2
- CACNA1G | c.6412A>G p.T2138A | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as COSV100661861; called by muse, mutect2
- KCNQ5 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs866590945, COSV100572979, COSV59667758; called by muse, mutect2
- SYNE1 | c.2540C>T p.S847L (on ENST00000367255 / NM_182961.4; = p.S854L on NM_033071.3) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as rs1314915829; called by muse, mutect2
- TACC2 | c.8747G>A p.R2916Q (on ENST00000334433; = p.R994Q on NM_006997.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758346924; called by muse, mutect2, varscan2
- KRT5 | c.927+1G>A p.X309_splice | Splice Site (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- MED23 | c.1137C>A p.F379L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF354B | c.1688_1689insGTTTCGGGC p.S563_S564insFRA | In Frame Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- SPRYD3 | c.372-133C>T | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs996769619; called by muse, mutect2, varscan2
- WHAMMP2 | chr15:28763524 G>A | 3'Flank (SNP) | VAF 9/24 reads (38%) | catalogued as rs1284092849; called by mutect2, varscan2
